Somatic mutation profile of tumor specimen TCGA-75-5126-01A (aliquot TCGA-75-5126-01A-01D-1753-08) from TCGA case TCGA-75-5126, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA.
Specimen TCGA-75-5126-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08b3fa43-ccda-4429-86aa-c61fe590c20b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-5126-10A (Blood Derived Normal), aliquot TCGA-75-5126-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8412af57-4d6f-44eb-be68-7c175c6b4be7

The open-access MAF lists 637 somatic variants for this specimen: 475 protein-altering or splice-affecting, 148 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 408, Silent 148, Nonsense Mutation 36, Splice Site 12, Frame Shift Del 11, Intron 6, 3'UTR 5, Splice Region 3, RNA 3, In Frame Del 2, Frame Shift Ins 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA10 | c.4206G>T p.E1402D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52227631; called by muse, mutect2, varscan2
- ABCD3 | c.1941C>G p.F647L | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV64644064; called by muse, mutect2, varscan2
- ACBD3 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV64730947; called by muse, mutect2, varscan2
- ACOT12 | c.1172G>T p.W391L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV56897056; called by muse, mutect2, varscan2
- ADAMTS12 | c.3032C>A p.S1011Y | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV61261584, COSV61273259; called by muse, mutect2, varscan2
- ADAMTS12 | c.1603G>T p.G535W | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61273270; called by muse, mutect2
- ADCY5 | c.1596C>A p.D532E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59197963, COSV59202217; called by muse, mutect2, varscan2
- ADCY8 | c.3436G>A p.A1146T | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.089); catalogued as COSV53920922; called by muse, mutect2, varscan2
- ADGRL3 | c.2424G>T p.E808D (on ENST00000506720 / NM_001322402.2; = p.E740D on NM_015236.6) | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.824); catalogued as COSV72231514; called by muse, mutect2, varscan2
- ADPRS | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV99255590; called by muse, mutect2
- AGO2 | c.2252G>T p.C751F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55050841; called by muse, mutect2, varscan2
- ALDH1A1 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV52793347; called by muse, mutect2, varscan2
- ANKIB1 | c.1493G>C p.G498A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV56064688, COSV56065801; called by muse, mutect2, varscan2
- ANKMY2 | c.850C>G p.Q284E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100187299, COSV61012436; called by muse, mutect2
- ANKRD44 | c.2013-2A>T p.X671_splice | Splice Site (SNP) | VAF 14/111 reads (13%) | catalogued as COSV56555153, COSV56562203; called by muse, mutect2, varscan2
- ANXA2 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60318211; called by muse, mutect2
- AOAH | c.115C>A p.H39N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV51747992; called by muse, mutect2, varscan2
- AQP10 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61475916; called by muse, mutect2, varscan2
- AREL1 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62667647; called by muse, mutect2
- ARFGEF1 | c.1774G>T p.G592* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV51614755; called by muse, mutect2, varscan2
- ARGFX | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV57683398; called by muse, mutect2, varscan2
- ARHGAP36 | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV52270404; called by muse, mutect2
- ARHGAP9 | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV62721337; called by muse, mutect2
- ARSI | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs745477091, COSV60818110; called by muse, mutect2, varscan2
- ASAP1 | c.2557G>T p.G853C | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as COSV63052754; called by muse, mutect2, varscan2
- ASPM | c.6178A>G p.K2060E | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV54135651; called by muse, mutect2
- ATF6 | c.758A>C p.Q253P | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV63409295; called by muse, mutect2, varscan2
- ATP2B2 | c.857T>A p.F286Y | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV59504659; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV59478854; called by muse, mutect2, varscan2
- AVPR2 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.688); catalogued as COSV61686730; called by muse, mutect2, varscan2
- BARD1 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99639362; called by muse, mutect2, varscan2
- BIRC6 | c.1947G>A p.M649I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV101428047, COSV70203883; called by muse, mutect2
- BIVM-ERCC5 | c.1445T>A p.M482K | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as COSV57281583; called by muse, mutect2
- BIVM-ERCC5 | c.2553T>A p.D851E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); catalogued as COSV63246611; called by mutect2, varscan2
- BMPR2 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.352); catalogued as COSV65812437; called by muse, mutect2, varscan2
- BPIFC | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV55914905; called by muse, mutect2
- BRINP3 | c.2079G>T p.Q693H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV66535685; called by muse, mutect2, varscan2
- BRINP3 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66535691; called by mutect2, varscan2
- BSN | c.9013C>G p.L3005V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.103); catalogued as rs777389415, COSV56524834; called by muse, mutect2, varscan2
- C21orf91 | c.36G>C p.L12F | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53032903; called by muse, mutect2
- C2orf78 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV68518781; called by muse, mutect2, varscan2
- CACNA1A | c.5736C>G p.I1912M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64207763; called by muse, varscan2
- CACNA1E | c.4144G>T p.V1382L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV62410597; called by muse, mutect2, varscan2
- CADM2 | c.331G>T p.V111F (on ENST00000407528 / NM_001167674.2; = p.V113F on NM_153184.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101058072; called by muse, mutect2, varscan2
- CADPS | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51869404, COSV51895192; called by muse, mutect2, varscan2
- CALHM1 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV53297363, COSV99588726; called by muse, mutect2
- CCDC40 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53903046; called by muse, mutect2, varscan2
- CCDC97 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs763113820, COSV99523816; called by muse, mutect2, varscan2
- CD163L1 | c.1863T>A p.C621* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV58022143; called by muse, mutect2, varscan2
- CD19 | c.1200C>A p.G400= | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100218216; called by muse, mutect2, varscan2
- CD19 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.525); catalogued as COSV100218219; called by muse, mutect2, varscan2
- CD58 | c.365-1G>C p.X122_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV59841919; called by muse, mutect2, varscan2
- CDH18 | c.2001C>A p.D667E | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56948513; called by muse, mutect2, varscan2
- CDH18 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.021); catalogued as COSV56948525; called by muse, mutect2, varscan2
- CDH22 | c.2047T>A p.Y683N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64839029; called by muse, mutect2
- CDH6 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54075658; called by muse, mutect2, varscan2
- CDH7 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59891550; called by muse, mutect2, varscan2
- CDH9 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50254879, COSV50270971; called by muse, mutect2, varscan2
- CDK15 | c.851+2T>A p.X284_splice (on ENST00000652192 / NM_001366386.2; = p.X233_splice on NM_139158.2) | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as COSV53637070; called by muse, mutect2, varscan2
- CELF1 | c.1454C>T p.P485L (on ENST00000358597 / NM_001376422.1; = p.P481L on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60114397; called by muse, mutect2, varscan2
- CENPI | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV54505162; called by muse, mutect2, varscan2
- CEP112 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV67143390; called by muse, mutect2, varscan2
- CEP290 | c.3721A>G p.K1241E | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV58354504; called by muse, mutect2
- CEP85 | c.526G>C p.A176P | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53331720; called by muse, mutect2
- CFAP47 | c.4654G>T p.G1552* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100545647, COSV57974272; called by muse, mutect2, varscan2
- CHD3 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV57878729; called by muse, mutect2
- CHD8 | c.992A>T p.Q331L (on ENST00000646647 / NM_001170629.2; = p.Q52L on NM_020920.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as COSV67872120; called by muse, mutect2
- CHRM3 | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV55098187; called by muse, mutect2
- CHST1 | c.1226C>A p.P409H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57325042; called by muse, mutect2
- CLEC16A | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68501214; called by muse, mutect2, varscan2
- CLEC1B | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.807); catalogued as COSV53726268; called by muse, mutect2, varscan2
- CLEC4D | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV55228806; called by muse, mutect2
- CLUL1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as COSV100621034, COSV58111541, COSV58111821; called by muse, mutect2, varscan2
- CNGB1 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51905006; called by muse, mutect2, varscan2
- CNTN6 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs1559540057, COSV100611155, COSV63183826; called by muse, mutect2, varscan2
- CNTNAP2 | c.363_364insT p.R122* | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | catalogued as COSV100669026; called by mutect2, pindel, varscan2
- CNTNAP2 | c.2870C>G p.S957C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV104421851, COSV62234383; called by muse, mutect2, varscan2
- CNTNAP2 | c.3262C>T p.R1088* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as rs766777011, COSV62164786; called by muse, mutect2, varscan2
- CNTNAP4 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56694384; called by muse, mutect2, varscan2
- COCH | c.1314T>A p.D438E (on ENST00000216361 / NM_001347720.1; = p.D373E on NM_004086.3) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53552346; called by muse, mutect2
- COL25A1 | c.1804C>A p.P602T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV67655887; called by muse, mutect2
- COL27A1 | c.3573G>T p.E1191D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV61929632; called by muse, mutect2, varscan2
- COL5A1 | c.2819G>T p.G940V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65673152; called by muse, mutect2, varscan2
- COL6A2 | c.2289C>A p.F763L | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100153980; called by muse, mutect2, varscan2
- COL9A3 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs140377811; called by muse, mutect2
- COMP | c.1273T>A p.F425I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV55876136; called by muse, mutect2, varscan2
- COQ8B | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV54688402; called by mutect2, varscan2
- CPD | c.2844G>A p.M948I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV56715150; called by muse, mutect2, varscan2
- CPNE8 | c.1437G>C p.M479I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV58842313, COSV58848917; called by muse, mutect2, varscan2
- CPS1 | c.1405G>T p.V469F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51820019; called by muse, mutect2, varscan2
- CRLF1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV66505211; called by muse, mutect2, varscan2
- CRYAB | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57052216; called by muse, mutect2
- CSRNP3 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV58783685; called by mutect2, varscan2
- CTNNA3 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101041713, COSV65527830; called by muse, mutect2, varscan2
- CTSD | c.1149G>T p.W383C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM061696, COSV52589550; called by muse, mutect2, varscan2
- CUL9 | c.5735G>T p.G1912V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.13); catalogued as COSV52732679; called by muse, mutect2, varscan2
- CXCR5 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52687934; called by muse, mutect2
- CYFIP1 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); catalogued as rs376633086; called by muse, mutect2, varscan2
- CYP27B1 | c.782T>G p.F261C | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56986068; called by muse, mutect2, varscan2
- DCLK1 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 13/103 reads (13%) | catalogued as COSV55201983; called by muse, mutect2, varscan2
- DENND5B | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV60906460; called by muse, mutect2, varscan2
- DIP2B | c.4483G>T p.V1495L | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749017384, COSV56589395, COSV99998807; called by muse, mutect2, varscan2
- DNAH8 | c.7670C>A p.P2557H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59470520; called by muse, mutect2, varscan2
- DPPA4 | c.230A>T p.K77M | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59512041; called by muse, mutect2, varscan2
- DPYS | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60912074; called by muse, mutect2, varscan2
- DRC1 | c.1669C>A p.R557S | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56534003; called by muse, mutect2
- DRD3 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV55682187; called by muse, varscan2
- DRGX | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65137192; called by muse, mutect2, varscan2
- DSCAM | c.719A>T p.Q240L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV68032942; called by muse, mutect2
- DSCAM | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.087); catalogued as COSV68650332; called by muse, mutect2, varscan2
- DST | c.3989A>T p.Q1330L (on ENST00000361203 / NM_001374722.1; = p.Q1004L on NM_001723.6) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV55032407; called by muse, mutect2, varscan2
- EGF | c.2948A>G p.Y983C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54482756; called by muse, mutect2, varscan2
- EIPR1 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV66132115; called by muse, mutect2
- EPHA6 | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67571678, COSV67587508; called by muse, varscan2
- EVI2B | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1485077087, COSV100445586; called by muse, mutect2, varscan2
- FAM104A | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101303958; called by muse, mutect2, varscan2
- FAM126B | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 13/121 reads (11%) | catalogued as COSV99628069; called by muse, mutect2
- FAM171B | c.385T>A p.Y129N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59006855; called by muse, mutect2, varscan2
- FAM47B | c.1545C>A p.D515E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as COSV61452702, COSV61456047; called by muse, mutect2, varscan2
- FAT3 | c.12803C>A p.P4268H | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53155493; called by muse, mutect2, varscan2
- FAT4 | c.11497G>T p.E3833* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV58701642; called by muse, mutect2, varscan2
- FBN2 | c.4879+1G>T p.X1627_splice | Splice Site (SNP) | VAF 27/394 reads (7%) | catalogued as COSV52535246; called by muse, mutect2
- FBN2 | c.3161del p.R1054Pfs*53 | Frame Shift Del (DEL) | VAF 13/110 reads (12%) | catalogued as COSV52517731; called by mutect2, pindel, varscan2
- FBN2 | c.827-1G>C p.X276_splice | Splice Site (SNP) | VAF 21/143 reads (15%) | catalogued as COSV52535261; called by muse, mutect2, varscan2
- FGB | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57419208; called by muse, mutect2, varscan2
- FGD4 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56783963; called by muse, mutect2, varscan2
- FGD5 | c.1813G>T p.G605C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53248940; called by muse, mutect2, varscan2
- FGFRL1 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV53257325, COSV99294664; called by muse, mutect2, varscan2
- FHOD3 | c.3726C>G p.F1242L (on ENST00000359247 / NM_001281739.3; = p.F1259L on NM_025135.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV57183076; called by muse, mutect2, varscan2
- FKBP9 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.045); catalogued as COSV54233470; called by muse, mutect2
- FLG | c.3189C>A p.H1063Q | Missense Mutation (SNP) | VAF 55/554 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV64246017; called by muse, mutect2
- FNTB | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV55763364; called by muse, mutect2, varscan2
- FRMD3 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58466785; called by muse, mutect2
- FRYL | c.4520G>A p.S1507N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV51956938; called by muse, mutect2, varscan2
- FSTL4 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54781270; called by muse, mutect2, varscan2
- FXR1 | c.514-2A>T p.X172_splice | Splice Site (SNP) | VAF 23/200 reads (12%) | catalogued as COSV59765162; called by muse, mutect2, varscan2
- G3BP1 | c.352G>T p.G118W | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62366178; called by muse, mutect2, varscan2
- GALNT16 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61887212; called by muse, mutect2
- GDF5 | c.1156A>C p.T386P | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV65502842; called by muse, mutect2, varscan2
- GFRAL | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs749227939, COSV61229928; called by muse, mutect2, varscan2
- GIMAP8 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV56232130, COSV56233053; called by muse, mutect2, varscan2
- GNGT1 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV50353238; called by muse, mutect2, varscan2
- GOLIM4 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58331263; called by muse, mutect2, varscan2
- GPATCH8 | c.4180C>G p.H1394D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV59197023; called by muse, mutect2, varscan2
- GPATCH8 | c.4077C>G p.I1359M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV59197040; called by muse, mutect2
- GPR148 | c.905C>A p.A302E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs1378132481, COSV59309108; called by muse, mutect2, varscan2
- GPR19 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60124480; called by muse, mutect2, varscan2
- GPR63 | c.779A>T p.Y260F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.565); catalogued as COSV57742780; called by muse, mutect2, varscan2
- GPX5 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as COSV69079766, COSV69079948; called by muse, mutect2, varscan2
- GRM7 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100736715, COSV63160300; called by muse, mutect2, varscan2
- GRM8 | c.1532A>C p.H511P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58854981; called by muse, mutect2
- GSTM2 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV53983561; called by muse, mutect2, varscan2
- GSTM5 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56659452; called by muse, mutect2, varscan2
- GTF3C1 | c.3568G>T p.G1190C | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as COSV62243827; called by muse, mutect2, varscan2
- H1-6 | c.201G>C p.K67N | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100619612; called by muse, mutect2, varscan2
- H2AC6 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV58414864, COSV58417237; called by muse, mutect2, varscan2
- HARS1 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.327); catalogued as COSV100298126, COSV56908692; called by muse, mutect2, varscan2
- HCLS1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1317265783, COSV57526450; called by muse, mutect2, varscan2
- HCRTR2 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV63798080; called by muse, mutect2
- HDAC7 | c.536A>G p.K179R (on ENST00000427332; = p.K218R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.993); catalogued as COSV50403280; called by muse, mutect2, varscan2
- HDGF | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs201482955; called by muse, mutect2, varscan2
- HFM1 | c.3503T>C p.I1168T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54034216; called by muse, mutect2
- HIPK3 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV57564651; called by muse, mutect2, varscan2
- HLTF | c.530-2A>G p.X177_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | catalogued as rs138362499; called by muse, mutect2
- HMCN1 | c.7594G>T p.G2532C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54927705; called by muse, mutect2, varscan2
- HPGDS | c.200T>A p.I67K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99755962; called by muse, mutect2
- HRH4 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56930130; called by muse, mutect2, varscan2
- HS3ST1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452472587, COSV50024410; called by muse, mutect2, varscan2
- HSPH1 | c.1080A>C p.K360N | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60712945; called by muse, mutect2, varscan2
- HTR3B | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV52746773; called by muse, mutect2
- HTRA4 | c.803C>A p.S268* | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | catalogued as COSV56760613; called by muse, mutect2, varscan2
- IGF2R | c.5881G>A p.E1961K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as COSV63631610; called by muse, mutect2
- IGHV1-46 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs781912006; called by muse, mutect2, varscan2
- IGKV1-16 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs776837256; called by muse, mutect2, varscan2
- IL9R | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV54901412; called by muse, mutect2
- IQSEC3 | c.2620A>G p.S874G (on ENST00000538872 / NM_001170738.2; = p.S571G on NM_015232.1) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100407793, COSV58288672; called by muse, mutect2, varscan2
- ITIH2 | c.2195C>G p.S732C | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64434591; called by muse, mutect2
- ITK | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM121080, COSV101439808, COSV70061950, COSV70062223; called by muse, mutect2
- KCNA4 | c.1480A>T p.S494C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60254946; called by muse, mutect2, varscan2
- KCNJ8 | c.745C>G p.P249A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53715759, COSV53717400, COSV99557671; called by muse, mutect2, varscan2
- KCNK13 | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751050914, COSV56415804; called by muse, mutect2, varscan2
- KCNQ2 | c.1940G>T p.R647L (on ENST00000359125 / NM_172107.4; = p.R619L on NM_004518.6) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV60543309, COSV60551351; called by muse, mutect2, varscan2
- KDELR1 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs1356919382, COSV58102681; called by muse, mutect2, varscan2
- KDM3B | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58693761; called by muse, mutect2, varscan2
- KLHDC7A | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101272829; called by muse, mutect2
- KLK8 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51591792, COSV99143854, COSV99144044; called by muse, mutect2, varscan2
- KMT2C | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51481886; called by muse, varscan2
- KMT2C | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV51481911; called by muse, varscan2
- KMT2D | c.15478G>C p.D5160H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56471877; called by muse, mutect2, varscan2
- KRTAP5-9 | c.241A>T p.S81C | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV73200248; called by muse, mutect2, varscan2
- KRTAP6-1 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 12/163 reads (7%) | PolyPhen possibly damaging (0.847); catalogued as COSV100228814, COSV58168585; called by muse, mutect2
- LACRT | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV57688568; called by muse, mutect2, varscan2
- LAMP2 | c.986A>T p.Y329F | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99568699; called by muse, mutect2, varscan2
- LDHA | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57041128; called by muse, mutect2, varscan2
- LEF1 | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV54471173; called by muse, mutect2
- LEF1 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.881); catalogued as COSV54471194; called by muse, mutect2
- LGSN | c.1166A>G p.N389S | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV101040449, COSV101040618; called by muse, mutect2, varscan2
- LHFPL3 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1367619501, COSV67817427; called by muse, mutect2
- LILRB2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58747505; called by muse, mutect2, varscan2
- LMOD2 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71755785; called by muse, mutect2, varscan2
- LPAR4 | c.1070C>A p.T357K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV70913185; called by muse, mutect2, varscan2
- LRP1B | c.13172G>C p.C4391S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV67257539; called by muse, mutect2
- LRP1B | c.11659G>C p.D3887H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.831); catalogued as COSV67257542; called by muse, mutect2
- LRRC37B | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100496404, COSV58954008; called by muse, mutect2, varscan2
- LRRC40 | c.233G>T p.W78L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63943041; called by muse, mutect2
- LRRIQ1 | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV67836148; called by muse, mutect2
- MAGEA8 | c.513A>T p.E171D | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV99674425, COSV99674717; called by muse, mutect2, varscan2
- MAGEB6 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV100983666, COSV66872362; called by muse, mutect2, varscan2
- MAGEC1 | c.2641T>C p.S881P | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV53578782; called by muse, mutect2, varscan2
- MAN2A1 | c.2225A>G p.D742G | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV54856403; called by muse, mutect2, varscan2
- MAP2 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV52298483, COSV52302766; called by muse, mutect2
- MARCHF11 | c.1098G>C p.R366S | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV60132940; called by muse, mutect2, varscan2
- MCF2 | c.288+1G>T p.X96_splice | Splice Site (SNP) | VAF 38/197 reads (19%) | catalogued as COSV58491896; called by muse, mutect2, varscan2
- MDGA2 | c.2746C>T p.H916Y (on ENST00000399232 / NM_001113498.2; = p.H618Y on NM_182830.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62099774; called by mutect2, varscan2
- MEGF10 | c.3061T>C p.C1021R | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57254227; called by muse, mutect2, varscan2
- MEGF8 | c.4886G>A p.R1629Q (on ENST00000251268 / NM_001271938.2; = p.R1562Q on NM_001410.3) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); catalogued as rs762874704, COSV52096675; called by muse, mutect2, varscan2
- MKI67 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV64075935; called by muse, mutect2, varscan2
- MOV10L1 | c.2059A>T p.T687S | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV53176938; called by muse, mutect2
- MPDZ | c.4187A>T p.D1396V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59922010; called by muse, mutect2
- MPHOSPH8 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64055428, COSV64057064; called by muse, mutect2, varscan2
- MRGPRX4 | c.105C>A p.C35* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as COSV100049776; called by muse, mutect2, varscan2
- MRPL51 | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV57520038; called by muse, mutect2
- MSH2 | c.1479G>T p.Q493H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV51877572, COSV51882932; called by muse, mutect2, varscan2
- MTCL1 | c.2863G>T p.E955* (on ENST00000306329 / NM_001378206.1; = p.E595* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV60409959; called by muse, mutect2, varscan2
- MTOR | c.6797G>C p.R2266P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1463184901, COSV63876076; called by muse, mutect2
- MTREX | c.943C>G p.P315A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57928935; called by muse, mutect2, varscan2
- MUC16 | c.17219C>G p.S5740* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as COSV67483296; called by muse, mutect2, varscan2
- MUC16 | c.13417G>A p.G4473R | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV67483302; called by muse, mutect2, varscan2
- MXRA5 | c.5874G>T p.Q1958H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV54245232; called by muse, mutect2, varscan2
- MYCBP2 | c.2981A>G p.Y994C (on ENST00000357337; = p.Y1032C on NM_015057.5) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV62033045; called by muse, mutect2, varscan2
- MYH7 | c.3869A>T p.Q1290L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV62522232; called by muse, mutect2, varscan2
- MYH8 | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67970328; called by muse, mutect2, varscan2
- MYO16 | c.535T>A p.Y179N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51810247; called by muse, mutect2
- MYO16 | c.3283G>C p.A1095P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV62758125; called by muse, mutect2, varscan2
- MYOD1 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100000354; called by muse, mutect2, varscan2
- MYOM2 | c.4222G>T p.V1408L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV50715889, COSV50751494; called by muse, mutect2, varscan2
- NAA16 | c.1409G>T p.R470M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65066183; called by muse, mutect2, varscan2
- NAALADL1 | c.896A>T p.N299I | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV60525356; called by muse, mutect2
- NBEA | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs756183902, COSV59810239; called by mutect2, varscan2
- NBEAL2 | c.5476C>T p.R1826C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs774486191, COSV52758173, COSV99437617; called by muse, mutect2, varscan2
- NCAPH | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV53637913; called by muse, mutect2, varscan2
- NCKAP5 | c.1529G>T p.S510I | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58444763, COSV58464921; called by muse, mutect2, varscan2
- NDUFS2 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57155654; called by muse, mutect2, varscan2
- NECAB2 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771571802, COSV100534065; called by muse, mutect2, varscan2
- NEXMIF | c.2335G>T p.A779S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.033); catalogued as COSV50071453; called by muse, mutect2, varscan2
- NFRKB | c.1691G>T p.R564L (on ENST00000446488 / NM_001143835.2; = p.R589L on NM_006165.3) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58759777; called by muse, mutect2, varscan2
- NLGN1 | c.2054C>G p.S685* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV64342665; called by muse, mutect2, varscan2
- NLRP14 | c.2124G>T p.L708= | Splice Region (SNP) | VAF 9/126 reads (7%) | catalogued as COSV55070555; called by muse, mutect2
- NR2C1 | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58011138, COSV58011738; called by muse, mutect2, varscan2
- NRF1 | c.401G>T p.C134F | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV56215244; called by muse, mutect2, varscan2
- NRF1 | c.908C>A p.S303* | Nonsense Mutation (SNP) | VAF 30/119 reads (25%) | catalogued as COSV56215263; called by muse, mutect2, varscan2
- NRK | c.4258G>C p.E1420Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV54590257, COSV54603265; called by muse, mutect2, varscan2
- NSUN2 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375926964; called by muse, mutect2, varscan2
- NSUN2 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99243372; called by mutect2, varscan2
- NTM | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66188738; called by muse, mutect2, varscan2
- NUDCD3 | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV62650825; called by muse, mutect2, varscan2
- OGFOD1 | c.1200G>C p.E400D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV60201211; called by muse, mutect2
- OLFM1 | c.733A>T p.R245W (on ENST00000371793 / NM_001282611.2; = p.R227W on NM_014279.5) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53281075; called by muse, mutect2, varscan2
- OLFML1 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV55080877; called by muse, mutect2
- OLIG3 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.585); catalogued as COSV100880312, COSV62988228; called by muse, mutect2, varscan2
- OOEP | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV64859466; called by muse, mutect2
- OR10G8 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV70909128, COSV70909148; called by muse, mutect2, varscan2
- OR10X1 | c.854C>A p.T285K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.728); catalogued as COSV63767793; called by muse, mutect2, varscan2
- OR11H4 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV59560741; called by muse, mutect2
- OR1J2 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58944909; called by muse, mutect2, varscan2
- OR1M1 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1345373299, COSV70037368; called by muse, mutect2, varscan2
- OR2M2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.045); catalogued as COSV62899105, COSV62899474; called by muse, mutect2, varscan2
- OR51F2 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59065696, COSV59066289; called by muse, mutect2, varscan2
- OR52N1 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57693854; called by muse, mutect2, varscan2
- OR5D14 | c.175A>T p.T59S | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV59457820; called by muse, mutect2, varscan2
- OR5L2 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV65724015, COSV65724856; called by muse, mutect2, varscan2
- OR5M8 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59117771; called by muse, mutect2
- OR6N1 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.339); catalogued as COSV58648526, COSV58649864; called by muse, mutect2
- OR6S1 | c.981G>T p.E327D | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57838905; called by muse, mutect2, varscan2
- OR8D2 | c.596T>A p.L199Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100659059; called by muse, mutect2, varscan2
- OR8S1 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV59600513; called by muse, mutect2, varscan2
- OXSM | c.1171G>T p.G391W | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55002343; called by muse, mutect2, varscan2
- PABPC1L | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53842156; called by muse, mutect2, varscan2
- PAIP2 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99497330; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.548G>T p.R183L (on ENST00000374531 / NM_001037293.2; = p.R215L on NM_053016.6) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV57118219, COSV57128894; called by muse, mutect2, varscan2
- PAMR1 | c.857C>A p.P286Q (on ENST00000619888 / NM_001001991.3; = p.P303Q on NM_015430.4) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV53515290; called by muse, mutect2, varscan2
- PCCA | c.1041C>G p.F347L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100886885, COSV66196838; called by muse, mutect2, varscan2
- PCDH10 | c.948G>T p.L316F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV99994162; called by muse, mutect2
- PCDH10 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52102266, COSV99994165; called by mutect2, varscan2
- PCDH10 | c.2984G>T p.G995V | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52100857; called by muse, mutect2, varscan2
- PCDHA4 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100793096, COSV63544790; called by muse, mutect2, varscan2
- PCDHA9 | c.1444G>C p.A482P | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.037); catalogued as COSV65324217, COSV65330952; called by muse, mutect2, varscan2
- PCDHB11 | c.1081C>G p.P361A | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.639); catalogued as rs782695602, COSV100697108; called by muse, mutect2, varscan2
- PCDHB11 | c.1082C>A p.P361Q | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV100697109; called by muse, mutect2, varscan2
- PCDHB4 | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV52025487; called by muse, mutect2, varscan2
- PCDHGA2 | c.1953G>T p.Q651H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54004544; called by muse, mutect2
- PCDHGA6 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV54004562; called by muse, mutect2, varscan2
- PCDHGA7 | c.1858G>T p.G620W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV54004605; called by muse, mutect2, varscan2
- PDGFD | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs765909253, COSV56388590; called by muse, mutect2, varscan2
- PDZRN3 | c.2532C>A p.D844E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV55211103; called by muse, mutect2, varscan2
- PDZRN4 | c.2743G>T p.A915S (on ENST00000402685 / NM_001164595.2; = p.A657S on NM_013377.4) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54211714; called by muse, mutect2, varscan2
- PEAK1 | c.2305C>T p.Q769* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | catalogued as COSV56940847; called by muse, mutect2
- PEAK1 | c.2102C>G p.S701* | Nonsense Mutation (SNP) | VAF 11/217 reads (5%) | catalogued as COSV56940875; called by muse, mutect2
- PEX5L | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV55853101; called by muse, mutect2, varscan2
- PFKFB4 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | PolyPhen benign (0.196); catalogued as COSV51682308; called by muse, mutect2, varscan2
- PGK2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV59163277; called by muse, mutect2
- PGLYRP2 | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.059); catalogued as COSV52996623; called by muse, mutect2, varscan2
- PHEX | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV65077757; called by muse, mutect2, varscan2
- PHLPP2 | c.1666G>T p.G556* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV62426590; called by muse, mutect2
- PKHD1 | c.9425C>A p.T3142N | Missense Mutation (SNP) | VAF 51/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61889811; called by muse, mutect2, varscan2
- PKHD1L1 | c.3818T>C p.M1273T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV65749658; called by muse, mutect2
- PLD1 | c.1996+1G>A p.X666_splice | Splice Site (SNP) | VAF 22/185 reads (12%) | catalogued as COSV60572411; called by muse, mutect2, varscan2
- PLD2 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.137); catalogued as COSV54008402; called by muse, varscan2
- PLEK | c.343A>T p.R115W | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52253272; called by muse, mutect2, varscan2
- PLEKHG7 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67338107; called by muse, varscan2
- PLIN2 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99439070; called by muse, mutect2, varscan2
- PLXNB2 | c.1949C>A p.S650* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100834077, COSV63783640; called by muse, varscan2
- PLXND1 | c.4521G>T p.R1507= | Splice Region (SNP) | VAF 6/53 reads (11%) | catalogued as COSV60717689; called by muse, mutect2, varscan2
- POLR1B | c.431A>T p.K144M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV54501970; called by muse, mutect2, varscan2
- POLR3H | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs577195318, COSV99347607; called by mutect2, varscan2
- POTEF | c.2522C>A p.S841Y | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV62543123; called by muse, mutect2, varscan2
- PRDM14 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52572110, COSV52574705; called by muse, mutect2, varscan2
- PSD2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs888462721, COSV51206681, COSV99217252; called by muse, mutect2, varscan2
- PTH2R | c.677C>A p.T226N | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV55919035; called by muse, mutect2
- QRICH2 | c.3264G>C p.K1088N | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53156547; called by muse, varscan2
- RAD21 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV52062288; called by muse, mutect2
- RANBP2 | c.7695G>T p.Q2565H | Missense Mutation (SNP) | VAF 42/391 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51706093; called by muse, mutect2, varscan2
- RANBP6 | c.3187G>T p.D1063Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV52391343, COSV99424309; called by muse, mutect2, varscan2
- RCC1 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100868176; called by muse, mutect2, varscan2
- REEP6 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99278781; called by muse, mutect2, varscan2
- RICTOR | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as rs1230687231, COSV57127950; called by muse, mutect2, varscan2
- RIMS1 | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53474518; called by muse, mutect2, varscan2
- RIMS2 | c.1175C>T p.S392L (on ENST00000666250 / NM_001348490.2; = p.S200L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.114); catalogued as COSV51709760, COSV99192570; called by muse, mutect2, varscan2
- RIPOR3 | c.2296C>T p.H766Y | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV50397948, COSV50402375; called by muse, mutect2, varscan2
- RNASE13 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.091); catalogued as COSV100409627; called by muse, mutect2, varscan2
- RNF123 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59691217; called by muse, mutect2, varscan2
- RNF26 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60989845; called by muse, mutect2, varscan2
- ROBO2 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV59930639; called by muse, mutect2, varscan2
- RPL23A | c.430T>G p.Y144D | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs1190528523, COSV99411836; called by muse, mutect2
- RRM2 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.139); catalogued as COSV100459588, COSV58817506; called by muse, mutect2
- RRP12 | c.3308A>G p.Q1103R | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV59670439; called by muse, mutect2, varscan2
- RTCA | c.46-2A>T p.X16_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV53121786; called by muse, mutect2, varscan2
- RTN3 | c.1208G>T p.G403V (on ENST00000377819 / NM_001265589.2; = p.G384V on NM_201428.3) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs1250232213, COSV58030623; called by muse, mutect2, varscan2
- RYR1 | c.5503G>C p.E1835Q | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV62106291; called by muse, mutect2, varscan2
- S1PR1 | c.312G>T p.L104F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV59514155; called by muse, mutect2, varscan2
- SAE1 | c.894G>T p.E298D | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99538092; called by muse, mutect2, varscan2
- SATB2 | c.1980C>G p.I660M | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV53481333, COSV53490395, COSV99611365; called by muse, mutect2
- SCAF8 | c.2437C>G p.L813V | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.117); catalogued as COSV65793238; called by muse, mutect2, varscan2
- SCML4 | c.395A>C p.Q132P | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64637219; called by muse, mutect2, varscan2
- SCN2A | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV51851357; called by muse, mutect2
- SCN2A | c.2644G>C p.G882R | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as COSV99332751; called by muse, mutect2, varscan2
- SDAD1 | c.1105A>T p.I369F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV62403516; called by muse, mutect2
- SEC63 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV64598397, COSV64601024; called by muse, mutect2
- SEMA3D | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV52396145, COSV52400596; called by muse, mutect2, varscan2
- SEMA6A | c.2028T>G p.H676Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV56713806; called by muse, mutect2
- SERPINA1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV63345446; called by muse, mutect2, varscan2
- SERPINA12 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.048); catalogued as COSV57945567; called by muse, mutect2, varscan2
- SETD2 | c.4450G>T p.E1484* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as COSV57446573; called by muse, mutect2, varscan2
- SGIP1 | c.1187C>A p.T396K | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as rs749240200, COSV52775923; called by muse, mutect2, varscan2
- SHLD1 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100290621; called by muse, mutect2, varscan2
- SHOX2 | c.553C>T p.Q185* (on ENST00000441443 / NM_006884.3; = p.Q209* on NM_003030.4) | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV67464466; called by muse, mutect2
- SIX2 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.089); catalogued as rs373961258; called by muse, mutect2, varscan2
- SLC2A3 | c.1252_1253insA p.L418Yfs*35 | Frame Shift Ins (INS) | VAF 27/120 reads (23%) | catalogued as COSV99306832; called by mutect2, pindel, varscan2
- SLC4A4 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52633784; called by muse, mutect2
- SLC4A4 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV52633793; called by muse, mutect2
- SLC6A11 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1348808621, COSV54391458, COSV99594849; called by muse, mutect2, varscan2
- SLC6A12 | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV62885829; called by muse, mutect2
- SLC8A1 | c.1593T>G p.I531M | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60492167; called by muse, mutect2, varscan2
- SLC9A4 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV54837522; called by muse, mutect2, varscan2
- SLFN11 | c.2315G>T p.G772V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV57700010; called by muse, mutect2, varscan2
- SLFN5 | c.1679A>T p.Q560L | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100249762; called by muse, mutect2, varscan2
- SMARCD1 | c.1485C>G p.F495L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV67412839; called by muse, mutect2
- SMO | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV50836998; called by muse, mutect2, varscan2
- SORCS3 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63819730; called by muse, mutect2, varscan2
- SOWAHB | c.1238A>T p.K413I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV57555015; called by muse, mutect2, varscan2
- SP4 | c.1699G>C p.G567R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99754834; called by muse, mutect2
- SPEG | c.4194C>G p.I1398M | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV56671292, COSV56676919; called by muse, mutect2, varscan2
- SPESP1 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.3); catalogued as COSV52993919; called by muse, mutect2
- ST18 | c.2334C>A p.H778Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52483364, COSV52494992; called by muse, mutect2, varscan2
- STAP1 | c.550C>G p.R184G | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55329407, COSV99609626; called by muse, mutect2, varscan2
- STK17B | c.515T>A p.L172H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.749); catalogued as COSV55829625; called by muse, mutect2, varscan2
- STUB1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99555897; called by muse, mutect2, varscan2
- SVEP1 | c.6392A>T p.Q2131L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as COSV52842475; called by muse, mutect2, varscan2
- SYMPK | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs540054802, COSV55609415; called by muse, mutect2, varscan2
- SYMPK | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV55614606; called by muse, mutect2, varscan2
- SYMPK | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55614620; called by muse, mutect2, varscan2
- SYNE1 | c.5256C>G p.I1752M (on ENST00000367255 / NM_182961.4; = p.I1759M on NM_033071.3) | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV55062518; called by muse, mutect2, varscan2
- SYT13 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50075890; called by muse, mutect2, varscan2
- TACC2 | c.3074C>T p.S1025F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57767202; called by muse, mutect2, varscan2
- TARBP1 | c.1924C>G p.L642V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1235157870, COSV50198223; called by muse, mutect2, varscan2
- TC2N | c.1284A>G p.I428M | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV61747761; called by muse, mutect2, varscan2
- TCF21 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99399719; called by muse, mutect2, varscan2
- TCHH | c.2743A>G p.R915G | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV64276911; called by muse, mutect2, varscan2
- TEK | c.1153C>A p.L385M | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66231715; called by muse, mutect2, varscan2
- TENM2 | c.3188C>A p.P1063H (on ENST00000518659 / NM_001122679.2; = p.P831H on NM_001080428.3) | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV69137948; called by muse, mutect2, varscan2
- TEP1 | c.1652A>T p.Q551L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV52997702; called by muse, mutect2, varscan2
- TEX15 | c.8332+1G>T p.X2778_splice (on ENST00000256246; = p.X3161_splice on NM_001350162.2) | Splice Site (SNP) | VAF 10/93 reads (11%) | catalogued as COSV56351452; called by muse, mutect2, varscan2
- TG | c.8094G>C p.K2698N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV55089258; called by muse, mutect2, varscan2
- TGM6 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs143085842, COSV52480301; called by muse, mutect2, varscan2
- TIAM1 | c.4474C>T p.Q1492* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV54566713; called by muse, mutect2, varscan2
- TMEM132D | c.1134C>A p.Y378* | Nonsense Mutation (SNP) | VAF 49/201 reads (24%) | catalogued as COSV70603145, COSV70617337; called by muse, mutect2, varscan2
- TMEM132E | c.2906C>A p.A969E (on ENST00000321639; = p.A1059E on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV58699526; called by muse, mutect2, varscan2
- TMEM63B | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV52481599; called by muse, mutect2, varscan2
- TMPRSS11A | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.135); catalogued as COSV58357755, COSV58360316; called by muse, mutect2
- TMTC1 | c.635G>T p.G212V (on ENST00000539277 / NM_001193451.2; = p.G104V on NM_175861.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55489924; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.073); catalogued as rs545906142, COSV64102108; called by muse, mutect2, varscan2
- TNRC6A | c.1075A>T p.S359C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV59368412; called by muse, mutect2
- TPBG | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63882304; called by muse, mutect2, varscan2
- TRAPPC9 | c.2534C>G p.A845G | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV66906902; called by muse, mutect2, varscan2
- TRIP12 | c.3446C>G p.S1149* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV52270094; called by muse, varscan2
- TRPC1 | c.2249T>C p.M750T (on ENST00000476941 / NM_001251845.2; = p.M716T on NM_003304.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.258); catalogued as COSV56428554; called by muse, mutect2, varscan2
- TRPC4 | c.1831G>T p.V611F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100157487; called by muse, mutect2, varscan2
- TSGA10IP | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV73245387; called by muse, mutect2, varscan2
- TSHZ2 | c.2570A>T p.Q857L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61590531; called by muse, mutect2, varscan2
- TSHZ3 | c.1598C>A p.A533E | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV53678843; called by muse, mutect2, varscan2
- TSPOAP1 | c.1891G>T p.V631L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV52115074; called by muse, mutect2
- TTF1 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV57506525; called by muse, mutect2, varscan2
- TTLL5 | c.3694A>T p.N1232Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV54040926; called by mutect2, varscan2
- TTN | c.93533C>A p.P31178H (on ENST00000591111; = p.P23754H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/168 reads (13%) | PolyPhen possibly damaging (0.487); catalogued as COSV60249950; called by muse, mutect2, varscan2
- TTN | c.82233C>A p.H27411Q (on ENST00000591111; = p.H19987Q on NM_003319.4) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | PolyPhen benign (0.099); catalogued as COSV60249990; called by muse, mutect2
- TTN | c.60460G>A p.E20154K (on ENST00000591111; = p.E12730K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | PolyPhen probably damaging (0.994); catalogued as COSV60250042; called by muse, mutect2, varscan2
- TTN | c.53011G>A p.G17671S (on ENST00000591111; = p.G10247S on NM_003319.4) | Missense Mutation (SNP) | VAF 21/133 reads (16%) | PolyPhen probably damaging (0.999); catalogued as rs753408795, COSV60250094; called by muse, mutect2, varscan2
- UBD | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV63543984; called by muse, mutect2, varscan2
- UBQLN3 | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.069); catalogued as COSV61165085; called by muse, mutect2
- UBQLNL | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100975184; called by muse, mutect2, varscan2
- USP54 | c.2202G>C p.E734D | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV60445971; called by muse, mutect2, varscan2
- USPL1 | c.2294G>T p.S765I | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55001583; called by muse, mutect2, varscan2
- UVRAG | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62108431; called by muse, mutect2
- UVRAG | c.2099G>T p.*700Lext*18 | Nonstop Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV62108441; called by muse, mutect2, varscan2
- VAV3 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100579282, COSV100580138; called by muse, mutect2, varscan2
- VAV3 | c.1823C>G p.P608R | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV100580140, COSV100580186; called by muse, mutect2
- VGLL3 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 10/107 reads (9%) | catalogued as COSV67354070; called by muse, mutect2
- VIRMA | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52589350; called by muse, mutect2
- VPS13B | c.7399G>A p.V2467I | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV62152695; called by muse, mutect2
- VPS13C | c.8744C>G p.S2915* (on ENST00000644861 / NM_020821.3; = p.S2872* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV51412115; called by muse, mutect2, varscan2
- VPS50 | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58510071; called by muse, mutect2, varscan2
- VPS50 | c.2089A>T p.T697S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as COSV59921696; called by muse, mutect2, varscan2
- VPS8 | c.2829C>G p.I943M (on ENST00000625842 / NM_001349294.1; = p.I941M on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as rs1428147533, COSV54993215; called by muse, mutect2, varscan2
- VWA3B | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV68245524; called by muse, mutect2
- WASF1 | c.742G>C p.G248R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV55620770; called by muse, mutect2, varscan2
- WDCP | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV54593349; called by mutect2, varscan2
- WDFY1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV51791701; called by muse, mutect2, varscan2
- WDR3 | c.2583G>T p.R861S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV60464865; called by muse, mutect2, varscan2
- WNT10A | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748131786, COSV51461426; called by muse, mutect2, varscan2
- XIRP2 | c.4539C>A p.N1513K (on ENST00000628543; = p.N1688K on NM_152381.6) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.532); catalogued as rs775296687, COSV54723754; called by muse, mutect2, varscan2
- XPNPEP3 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 13/128 reads (10%) | catalogued as COSV64028028, COSV64028165; called by muse, mutect2
- ZBBX | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV56791058; called by muse, mutect2, varscan2
- ZC3H12B | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV59050589; called by muse, mutect2, varscan2
- ZC3H14 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.943); catalogued as COSV51772327; called by muse, mutect2, varscan2
- ZNF197 | c.363G>C p.Q121H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV60361604; called by muse, mutect2
- ZNF451 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as COSV62599193; called by muse, mutect2
- ZNF454 | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV60769639; called by muse, mutect2, varscan2
- ZNF461 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV64454299, COSV64454716; called by muse, mutect2, varscan2
- ZNF563 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV53371640; called by muse, mutect2, varscan2
- ZNF594 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | catalogued as COSV101280534; called by muse, mutect2, varscan2
- ZNF638 | c.4301C>G p.A1434G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as COSV52493536; called by muse, mutect2
- ZNF790 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.725); catalogued as COSV63213036; called by muse, mutect2, varscan2
- ZNF804A | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV56463790; called by muse, mutect2, varscan2
- ZP4 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63911273, COSV63913089; called by muse, mutect2, varscan2
- ZZZ3 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV66234745; called by muse, mutect2, varscan2
- ACACA | c.5632G>T p.V1878F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADAMTS7 | c.3715_3723del p.T1239_P1241del | In Frame Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- DNAH8 | c.1636del p.D546Tfs*70 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel, varscan2
- FAM131B | c.764del p.G255Efs*9 | Frame Shift Del (DEL) | VAF 32/167 reads (19%) | called by mutect2, pindel, varscan2
- FCGBP | c.5488A>G p.N1830D | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.35); called by muse, mutect2
- GPRC6A | c.331del p.A111Qfs*4 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- GRHL1 | c.1579_1585del p.E527Rfs*18 | Frame Shift Del (DEL) | VAF 27/197 reads (14%) | called by mutect2, pindel, varscan2
- IGLV2-23 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- IGLV3-9 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KDM6A | c.4116del p.F1372Lfs*4 | Frame Shift Del (DEL) | VAF 23/135 reads (17%) | called by mutect2, pindel, varscan2
- LAT2 | c.47_55del p.V16_L18del | In Frame Del (DEL) | VAF 10/124 reads (8%) | called by mutect2, pindel
- LZTS1 | c.849del p.F284Lfs*70 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, varscan2
- PAK5 | c.347del p.G116Vfs*57 | Frame Shift Del (DEL) | VAF 33/220 reads (15%) | called by mutect2, pindel, varscan2
- PLD1 | c.1540-2A>T p.X514_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2
- RBP3 | c.2798T>G p.L933R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC2A14 | c.95del p.P32Qfs*3 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- STT3A | c.817del p.V273Sfs*18 | Frame Shift Del (DEL) | VAF 30/318 reads (9%) | called by mutect2, pindel
- TRBV4-2 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.100488_100497del p.M33497Tfs*20 (on ENST00000591111; = p.M26073Tfs*20 on NM_003319.4) | Frame Shift Del (DEL) | VAF 26/209 reads (12%) | called by mutect2, pindel, varscan2
- A1BG | c.804G>T p.A268= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV54052773; called by mutect2, varscan2
- ADAM33 | c.465C>A p.P155= | Silent (SNP) | VAF 16/181 reads (9%) | catalogued as COSV62936290; called by muse, mutect2
- ADGRE1 | c.693C>T p.I231= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV51679163; called by muse, mutect2, varscan2
- ADGRG4 | c.7710G>A p.R2570= | Silent (SNP) | VAF 54/414 reads (13%) | catalogued as COSV54963595; called by muse, varscan2
- AGAP1 | c.1926C>T p.L642= (on ENST00000304032 / NM_001037131.3; = p.L589= on NM_014914.5) | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as COSV58335664; called by muse, mutect2
- ALX1 | c.510G>A p.E170= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV57493670; called by muse, mutect2, varscan2
- ANKRD33 | c.648C>A p.S216= (on ENST00000340970 / NM_001304459.2; = p.S341= on NM_182608.4) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100001095, COSV56607835; called by muse, mutect2, varscan2
- AP3B1 | c.2217A>T p.T739= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV54889763; called by muse, mutect2
- AQP8 | c.528C>T p.A176= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs1470308947, COSV99564080; called by muse, mutect2, varscan2
- ARL13B | c.867G>A p.L289= (on ENST00000394222 / NM_001174150.2; = p.L182= on NM_144996.4) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV57400506; called by muse, mutect2, varscan2
- BEND3 | c.486C>T p.S162= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV100944647; called by muse, mutect2, varscan2
- BICC1 | c.753T>A p.T251= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV54065712; called by muse, mutect2, varscan2
- BRINP2 | c.1401C>T p.A467= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV64179327; called by muse, mutect2
- C9 | c.798C>A p.G266= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV54679856; called by muse, mutect2
- CADM3 | c.1008C>T p.I336= (on ENST00000368125 / NM_001127173.3; = p.I370= on NM_021189.5) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs767354987, COSV63675782; called by mutect2, varscan2
- CDH11 | c.2082A>G p.K694= | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as COSV51772118; called by muse, mutect2, varscan2
- CDH20 | c.1923C>A p.S641= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV53015408; called by muse, mutect2, varscan2
- CENPN | c.504G>C p.L168= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100001503; called by muse, mutect2
- CFAP100 | c.1383C>A p.A461= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV61504119; called by muse, mutect2, varscan2
- CLCA4 | c.1560C>G p.L520= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV55370109; called by muse, mutect2, varscan2
- CRYGB | c.414C>T p.P138= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV53680832; called by muse, mutect2, varscan2
- CSPG4 | c.4926C>A p.A1642= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV57899682; called by muse, mutect2
- CSTL1 | c.33G>T p.L11= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV55678808, COSV99851191; called by muse, mutect2, varscan2
- CTSF | c.930C>T p.L310= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV59750131; called by muse, mutect2, varscan2
- DCAF12L2 | c.919C>A p.R307= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as COSV63582223, COSV63583649; called by muse, mutect2, varscan2
- DCTN5 | c.540G>T p.T180= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV55616115; called by muse, mutect2, varscan2
- DDO | c.609C>G p.V203= (on ENST00000368924 / NM_001368172.1; = p.V144= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/167 reads (10%) | catalogued as COSV64470423; called by muse, mutect2, varscan2
- DDX58 | c.480C>T p.L160= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV65884312; called by muse, mutect2, varscan2
- DGKB | c.240T>A p.T80= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV51808166, COSV99343965; called by muse, mutect2, varscan2
- DNAH2 | c.13119G>A p.K4373= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV66723919; called by muse, mutect2, varscan2
- DOP1B | c.6510T>C p.F2170= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV67695130; called by muse, mutect2, varscan2
- DSCAM | c.2988A>C p.I996= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV101259581, COSV68032936; called by muse, mutect2
- DYNC2H1 | c.6870A>T p.V2290= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV62102673; called by muse, mutect2, varscan2
- ENOPH1 | c.693G>A p.V231= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99908621, COSV99908765; called by muse, mutect2, varscan2
- EPCAM | c.357G>A p.V119= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV55394137; called by muse, mutect2, varscan2
- EPHA5 | c.1113T>C p.T371= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV56655670, COSV56663720; called by muse, mutect2
- EPHA6 | c.1776C>A p.P592= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV67587519; called by muse, varscan2
- EPM2AIP1 | c.387G>C p.L129= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV51622370; called by muse, mutect2
- ERG28 | c.165C>T p.I55= | Silent (SNP) | VAF 47/243 reads (19%) | catalogued as COSV56363675; called by muse, mutect2, varscan2
- FAM47C | c.3063T>A p.V1021= | Silent (SNP) | VAF 33/191 reads (17%) | catalogued as COSV63729245; called by muse, mutect2, varscan2
- FBN2 | c.8475C>A p.I2825= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV52535224; called by muse, mutect2, varscan2
- GABRG1 | c.933G>T p.L311= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV54959270; called by muse, varscan2
- GGNBP2 | c.786C>T p.C262= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as rs779575680; called by muse, mutect2, varscan2
- GIMAP2 | c.285G>A p.V95= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99785459; called by muse, mutect2, varscan2
- GIMAP8 | c.1593G>A p.V531= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV56233058; called by muse, mutect2, varscan2
- GLI3 | c.792G>T p.G264= | Silent (SNP) | VAF 21/213 reads (10%) | catalogued as rs763668102, COSV67893142; called by muse, mutect2
- GOLPH3 | c.873G>C p.A291= | Silent (SNP) | VAF 35/189 reads (19%) | catalogued as COSV54061307, COSV54062158; called by muse, mutect2, varscan2
- GPR19 | c.223C>T p.L75= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100196961; called by muse, varscan2
- HDAC2 | c.207C>T p.H69= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs1365036593, COSV64039097; called by muse, mutect2, varscan2
- HEPH | c.3105G>A p.V1035= (on ENST00000343002; = p.V768= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1259195783, COSV57969398; called by muse, varscan2
- HEPH | c.3165C>A p.G1055= (on ENST00000343002; = p.G788= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV57969422; called by muse, varscan2
- HMMR | c.816G>A p.K272= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV62375209; called by muse, mutect2
- HRH4 | c.915G>T p.L305= | Silent (SNP) | VAF 66/278 reads (24%) | catalogued as COSV99907951; called by muse, mutect2, varscan2
- HTR1A | c.642C>G p.L214= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs374689000, COSV60502293; called by muse, mutect2, varscan2
- HTT | c.2640G>T p.V880= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV61866937; called by muse, mutect2, varscan2
- IGSF1 | c.900C>T p.D300= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs376545217, COSV63835989; called by muse, mutect2, varscan2
- IRGC | c.483G>A p.K161= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54985635; called by muse, varscan2
- ITGA4 | c.528G>T p.L176= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV51998684, COSV52002863, COSV52005740; called by muse, mutect2, varscan2
- ITGAM | c.324C>A p.T108= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs370133643, COSV54940737; called by muse, mutect2, varscan2
- KLHL9 | c.33C>T p.G11= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100757141; called by muse, mutect2, varscan2
- KMT2E | c.3543C>G p.L1181= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV57577762; called by muse, mutect2
- KRTAP10-5 | c.120C>T p.V40= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100554794; called by muse, mutect2, varscan2
- KRTAP22-1 | c.36C>T p.G12= | Silent (SNP) | VAF 11/205 reads (5%) | catalogued as COSV100588938; called by muse, mutect2
- LAMA5 | c.8142C>T p.A2714= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs1402532269, COSV53368159; called by muse, mutect2
- LRCH4 | c.1332G>T p.G444= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV59644131; called by muse, mutect2, varscan2
- LRP1 | c.8103C>T p.F2701= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs368477109; called by muse, mutect2, varscan2
- LZTS2 | c.426G>A p.L142= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs1158453948, COSV64652453; called by muse, mutect2, varscan2
- MAGEB3 | c.169A>C p.R57= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV64397571; called by muse, mutect2, varscan2
- MAP3K19 | c.1759T>C p.L587= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as COSV59641182; called by muse, mutect2, varscan2
- MAST4 | c.465G>C p.L155= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV68242764; called by muse, mutect2, varscan2
- MCAM | c.777G>T p.V259= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV50652727; called by muse, mutect2
- MSC | c.549G>A p.V183= | Silent (SNP) | VAF 45/447 reads (10%) | catalogued as COSV57697310; called by muse, mutect2, varscan2
- MTARC1 | c.519G>T p.L173= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV65056087; called by muse, mutect2, varscan2
- MYO7B | c.5943C>A p.A1981= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV61444342; called by muse, mutect2, varscan2
- NAALAD2 | c.1119T>C p.F373= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as COSV58964526; called by muse, mutect2, varscan2
- NFAT5 | c.1776G>A p.L592= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV63030889; called by muse, mutect2, varscan2
- NLRP13 | c.972G>A p.E324= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV61623537; called by muse, mutect2, varscan2
- NLRP9 | c.843A>G p.Q281= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV60466478; called by muse, mutect2, varscan2
- NOC3L | c.1863G>A p.Q621= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs893528427, COSV64930373; called by muse, mutect2, varscan2
- NOD1 | c.2583G>A p.A861= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs760276479, COSV56113355; called by muse, mutect2, varscan2
- NOD2 | c.1642C>T p.L548= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV56053736; called by muse, mutect2, varscan2
- NPM1 | c.426G>T p.R142= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV51571430; called by muse, mutect2, varscan2
- NYAP2 | c.589C>A p.R197= | Silent (SNP) | VAF 23/217 reads (11%) | catalogued as rs1559220841, COSV56013284, COSV56015077; called by muse, mutect2, varscan2
- OR14K1 | c.864C>T p.Y288= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99315367; called by muse, mutect2
- OR1S2 | c.789G>T p.L263= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV56920147; called by muse, mutect2, varscan2
- OR2B2 | c.444C>A p.S148= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100308192; called by muse, mutect2, varscan2
- OR4D2 | c.921T>A p.V307= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV73459839; called by muse, mutect2, varscan2
- OR4K15 | c.780C>A p.A260= (on ENST00000305051; = p.A236= on NM_001005486.1) | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as rs1277871569, COSV59302531; called by muse, mutect2
- OR4P4 | c.72C>T p.L24= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV58923196; called by muse, mutect2, varscan2
- OR5I1 | c.753G>T p.T251= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs992238881, COSV100041606, COSV56886819, COSV56888334; called by muse, mutect2
- OR8I2 | c.9C>A p.G3= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as COSV56167495, COSV56169630; called by muse, mutect2
- P3H1 | c.1650G>A p.E550= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV52536343; called by muse, mutect2, varscan2
- PCDH15 | c.5001A>C p.A1667= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100905296; called by muse, mutect2, varscan2
- PCDHA1 | c.339G>A p.P113= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV65376176, COSV65377373; called by muse, mutect2, varscan2
- PCDHA6 | c.12C>A p.T4= | Silent (SNP) | VAF 30/191 reads (16%) | catalogued as rs782158590, COSV65355786, COSV65357756; called by muse, mutect2, varscan2
- PCDHA6 | c.2226C>A p.S742= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV65346434; called by muse, mutect2, varscan2
- PCDHB1 | c.2220G>A p.L740= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV60632638; called by muse, mutect2, varscan2
- PCDHGA6 | c.1359C>G p.P453= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs746357528, COSV54004581; called by muse, mutect2, varscan2
- PDE8B | c.1785C>T p.T595= | Silent (SNP) | VAF 14/181 reads (8%) | catalogued as COSV53742785; called by muse, mutect2
- PGLYRP3 | c.969G>A p.L323= | Silent (SNP) | VAF 47/271 reads (17%) | catalogued as COSV51952002; called by muse, mutect2, varscan2
- POLR3E | c.931C>T p.L311= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs58061211, COSV55402632; called by muse, mutect2, varscan2
- PREX1 | c.3186G>T p.R1062= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV64255331; called by muse, mutect2
- PRRT1 | c.816C>A p.S272= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52999276; called by muse, mutect2
- PTPN11 | c.450T>C p.S150= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as COSV61011666; called by muse, mutect2, varscan2
- PTPRD | c.1629C>T p.T543= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as rs758313334, COSV61972306; called by muse, mutect2, varscan2
- PXDNL | c.1713G>C p.G571= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV62495215; called by muse, mutect2
- RBL2 | c.813C>T p.D271= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as COSV50884336; called by muse, mutect2, varscan2
- RELN | c.5838C>A p.I1946= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs759612378, COSV58994923, COSV59025189; called by muse, mutect2, varscan2
- RELN | c.786T>C p.S262= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV59025200; called by muse, mutect2, varscan2
- RNASE11 | c.555A>T p.T185= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV60088039; called by muse, mutect2, varscan2
- RPL7L1 | c.204C>T p.S68= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100491770; called by muse, mutect2
- RPS14 | c.270C>T p.I90= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100365335; called by muse, mutect2, varscan2
- RRNAD1 | c.870G>C p.L290= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100836954, COSV100836973; called by muse, mutect2, varscan2
- RTL3 | c.936C>A p.L312= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV58185220; called by muse, mutect2
- S1PR5 | c.36C>T p.S12= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV61014425; called by muse, mutect2
- SCEL | c.714C>T p.I238= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV62994233; called by muse, mutect2
- SCGB1A1 | c.42C>G p.L14= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV53473843; called by muse, mutect2, varscan2
- SCN1A | c.1671G>A p.L557= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV57681612; called by muse, mutect2, varscan2
- SCN5A | c.5667C>T p.Y1889= (on ENST00000333535 / NM_198056.3; = p.Y1888= on NM_000335.5) | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs1438433663, COSV61136205; called by muse, varscan2
- SCRIB | c.4587G>T p.T1529= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV57591653; called by muse, mutect2
- SLC17A7 | c.369T>C p.F123= | Silent (SNP) | VAF 39/242 reads (16%) | catalogued as COSV55549089; called by muse, mutect2, varscan2
- SLC18A3 | c.1452G>T p.V484= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV60330285; called by muse, mutect2, varscan2
- SLC45A2 | c.1281G>T p.L427= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as COSV56874327; called by muse, mutect2, varscan2
- SLC52A3 | c.927C>T p.F309= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs781422986, COSV54078445; called by muse, mutect2, varscan2
- SLCO1A2 | c.1818A>T p.A606= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56607948; called by muse, mutect2, varscan2
- SPAG16 | c.729G>T p.L243= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV55988533; called by muse, mutect2, varscan2
- ST6GAL2 | c.306C>A p.S102= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV64527611, COSV64530680; called by muse, mutect2, varscan2
- STRN | c.1395C>G p.G465= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV55750896; called by mutect2, varscan2
- SWT1 | c.1227A>G p.T409= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV62257991; called by muse, mutect2, varscan2
- TECTA | c.2004G>T p.T668= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV50769160; called by muse, mutect2, varscan2
- TEP1 | c.6330C>T p.V2110= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV52997688; called by muse, mutect2
- TGDS | c.633A>T p.I211= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV54302129; called by muse, mutect2, varscan2
- TLN1 | c.5823C>T p.P1941= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV59210485; called by muse, mutect2, varscan2
- TPCN2 | c.1458C>T p.L486= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV53732630; called by muse, mutect2, varscan2
- TPGS2 | c.606G>T p.L202= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV57541296; called by muse, mutect2, varscan2
- TPP2 | c.1878C>A p.L626= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV65754208; called by muse, mutect2, varscan2
- TRAF1 | c.576G>C p.G192= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV65868543, COSV65869151; called by muse, mutect2, varscan2
- TRPM8 | c.2199C>A p.S733= | Silent (SNP) | VAF 47/379 reads (12%) | catalogued as COSV61223384; called by muse, mutect2, varscan2
- TUBA3D | c.546G>A p.V182= | Silent (SNP) | VAF 20/292 reads (7%) | catalogued as rs1183299030, COSV58310654, COSV58312875; called by muse, mutect2
- TUBB1 | c.645G>A p.L215= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV53887888; called by muse, mutect2, varscan2
- VNN2 | c.843A>T p.A281= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV58473734; called by muse, mutect2
- WDR7 | c.729C>T p.A243= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as rs143311376; called by muse, mutect2, varscan2
- WNK4 | c.3702G>C p.V1234= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV55908637; called by muse, mutect2, varscan2
- ZAN | c.4773G>T p.G1591= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV61813409; called by muse, mutect2, varscan2
- ZAN | c.7182C>A p.T2394= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV61813425; called by muse, mutect2, varscan2
- ZFAT | c.1878G>T p.T626= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs777603767, COSV64743557; called by muse, mutect2, varscan2
- ZNF154 | c.93T>A p.L31= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV101377532; called by muse, mutect2, varscan2
- ZNF804A | c.897C>A p.V299= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV56436422; called by muse, mutect2, varscan2
- AL590867.2 | n.223C>A | RNA (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*132G>A | 3'UTR (SNP) | VAF 11/83 reads (13%) | catalogued as COSV59504638; called by muse, mutect2, varscan2
- CDK9 | c.*2G>T | 3'UTR (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100953692; called by muse, mutect2, varscan2
- CTHRC1 | c.150+760T>A | Intron (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100373024; called by muse, mutect2, varscan2
- DEFB119 | c.61+1374G>A | Intron (SNP) | VAF 15/86 reads (17%) | catalogued as rs866508552, COSV59265675; called by muse, mutect2, varscan2
- HDAC9 | c.2577+22C>G | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs1177788689; called by muse, mutect2, varscan2
- HNF4G | c.-23-3773A>G | Intron (SNP) | VAF 13/110 reads (12%) | catalogued as COSV100584496; called by muse, mutect2, varscan2
- KCNC2 | c.*2006T>A | 3'UTR (SNP) | VAF 8/61 reads (13%) | catalogued as COSV54375807; called by muse, varscan2
- METTL17 | c.*2G>C | 3'UTR (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100068661; called by muse, mutect2
- MIR509-3 | n.17G>A | RNA (SNP) | VAF 32/259 reads (12%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2394+30A>T | Intron (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100793623; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185088G>T | Intron (SNP) | VAF 27/154 reads (18%) | catalogued as COSV100302749; called by muse, mutect2, varscan2
- SHISAL2A | c.*2C>T | 3'UTR (SNP) | VAF 14/277 reads (5%) | catalogued as COSV101284270; called by muse, mutect2
- SNORD115-26 | n.73G>C | RNA (SNP) | VAF 20/284 reads (7%) | catalogued as rs758965894; called by muse, mutect2
